Gene-level copy-number profile of tumor specimen TCGA-21-5784-01A from TCGA case TCGA-21-5784, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 80.4 years (29,362 days).
Specimen TCGA-21-5784-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.9951f1dd-82b1-48ff-b03c-2d0822dca2c3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-21-5784-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4e89ac9b-3e58-4e02-b6b5-546511efd870

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 36; copy number 1: 4,772; copy number 2: 37,386; copy number 3: 7,989; copy number 4: 7,614; copy number 5: 954; copy number 6: 274; copy number 7: 713; copy number 8: 41; copy number 14: 2; copy number 20: 33.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-21-5784-01A-01D-1631-01): tumor purity 0.18, ploidy 2.39, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 36 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:109,130,293–110,172,512, 11 genes (within-gene range 0–2): FRRS1L, EPB41L4B, RNU6-984P, MTND2P11, Y_RNA, PTPN3, PALM2AKAP2, MIR3927, YBX1P6, AL158829.1, AL158823.1.
- chr14:71,734,927–73,274,640, 25 genes: AC004900.1, AC005993.1, RGS6, Y_RNA, AC004828.2, MIR7843, AC004828.1, DPF3, AL392024.1, Y_RNA, DCAF4, AC007160.1, AL442663.4, AL442663.1, ZFYVE1, RN7SL586P, AL442663.3, RBM25, AL442663.2, PSEN1, AC004858.1, PAPLN, AC004846.1, RNU6-419P, AC004846.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,017 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:134,065,303–198,222,513, 1,107 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 7 (broad region; genes not listed).
- chr7:36,001,317–37,586,329, 31 genes, copy number 6 (within-gene range 4–6): AC083864.2, AC083864.4, AC083864.1, AC083864.3, MARK2P13, AC078841.1, EEPD1, AC007327.1, AC007327.2, AC006960.1, AC006960.3, KIAA0895, Y_RNA, ANLN, AC006960.2, AOAH, AOAH-IT1, AC007349.4, AC007349.1, AC007349.3, NPM1P18, AC007349.2, ELMO1, MIR1200, ELMO1-AS1, RPS17P13, RNU6-565P, RPS10P14, AC078843.1, Y_RNA, NECAP1P1.
- chr7:106,248,298–106,315,743, 3 genes, copy number 7: NAMPT, AC007032.1, LARP1BP2.
- chr8:37,762,595–39,580,134, 55 genes, copy number 8–20: PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1.
- chr8:132,685,007–133,814,537, 26 genes, copy number 6 (within-gene range 4–6): TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3.
- chr20:87,250–2,664,219, 85 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,772. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
